Somatic mutation profile of tumor specimen TCGA-77-A5G8-01B (aliquot TCGA-77-A5G8-01B-11D-A27K-08) from TCGA case TCGA-77-A5G8, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.0 years (25,921 days).
Specimen TCGA-77-A5G8-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4f0bf59-598b-41e9-9cba-dfb37a318813.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-77-A5G8-10A (Blood Derived Normal), aliquot TCGA-77-A5G8-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3d0e81e-0377-48bc-b5e1-6777d8e88b97

The open-access MAF lists 239 somatic variants for this specimen: 179 protein-altering or splice-affecting, 53 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 151, Silent 53, Nonsense Mutation 13, Splice Site 6, Frame Shift Del 3, RNA 3, Intron 3, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, Nonstop Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.3991C>T p.R1331C | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs760544654, CM141924, COSV66330033; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.825T>G p.C275W | Missense Mutation (SNP) | VAF 18/38 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555525279, CM152980, COSV52759232, COSV52912941, COSV53086963; ClinVar: likely pathogenic; called by muse, varscan2
- ABCA5 | c.1586G>T p.G529V | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101201026; called by muse, mutect2, varscan2
- ACSS3 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV54087586, COSV99698395; called by muse, mutect2, varscan2
- ACTR6 | c.591T>A p.D197E | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.76); catalogued as COSV99498515; called by muse, mutect2, varscan2
- ADGRB3 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV65419105; called by muse, mutect2, varscan2
- AGBL2 | c.550G>C p.E184Q | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as COSV100101366, COSV54093060; called by muse, mutect2, varscan2
- AK5 | c.289C>G p.R97G (on ENST00000354567 / NM_174858.3; = p.R71G on NM_012093.4) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV100481375, COSV100481586; called by muse, mutect2, varscan2
- ALOXE3 | c.325T>C p.C109R | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV100502923; called by muse, mutect2, varscan2
- ALPK3 | c.3944C>T p.P1315L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV99360356, COSV99360780; called by muse, mutect2, varscan2
- ANGEL1 | c.1593G>T p.M531I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51874224, COSV99200333; called by muse, mutect2, varscan2
- ANKRD35 | c.2630A>C p.E877A | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as COSV100841649; called by muse, mutect2, varscan2
- AP1M2 | c.1129G>C p.G377R | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV51566479, COSV51568642, COSV99140743; called by muse, mutect2, varscan2
- APOB | c.12262T>A p.Y4088N | Missense Mutation (SNP) | VAF 27/179 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.429); catalogued as COSV99264074; called by muse, mutect2, varscan2
- ARCN1 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV99873484; called by muse, mutect2, varscan2
- ARHGEF38 | c.332A>G p.N111S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs765574141, COSV99486102; called by muse, mutect2, varscan2
- ARMH4 | c.1436A>G p.Q479R | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0.023); catalogued as COSV99957757; called by muse, mutect2, varscan2
- ASCC2 | c.2162G>T p.R721L | Missense Mutation (SNP) | VAF 166/745 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs139016848, COSV100316078; called by muse, mutect2, varscan2
- ASPM | c.2629G>T p.G877C | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99659719; called by muse, mutect2, varscan2
- ATP10A | c.2635C>T p.R879C | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs763611613, COSV63512846, COSV63515586; called by muse, mutect2, varscan2
- ATP11C | c.2072G>T p.C691F | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100557545; called by muse, mutect2, varscan2
- BRWD3 | c.3031A>G p.I1011V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.82); PolyPhen benign (0.014); catalogued as COSV100955738; called by muse, mutect2, varscan2
- C10orf53 | c.401G>T p.C134F | Missense Mutation (SNP) | VAF 65/164 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as COSV100935001; called by muse, mutect2, varscan2
- CCAR1 | c.3394G>A p.D1132N | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.068); catalogued as COSV99770693; called by muse, mutect2
- CCNB1IP1 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100738511; called by muse, mutect2, varscan2
- CCT6A | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV99303252; called by muse, mutect2, varscan2
- CDH10 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.209); catalogued as rs903128657, COSV100050371, COSV52573159; called by muse, mutect2, varscan2
- CDK14 | c.649T>A p.L217I (on ENST00000380050 / NM_001287135.2; = p.L199I on NM_012395.3) | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99724061; called by muse, mutect2
- CFH | c.3626C>A p.S1209* | Nonsense Mutation (SNP) | VAF 22/112 reads (20%) | catalogued as COSV100808997; called by muse, mutect2, varscan2
- CIBAR2 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV101608263; called by muse, mutect2, varscan2
- CNTNAP4 | c.353G>A p.W118* | Nonsense Mutation (SNP) | VAF 27/115 reads (23%) | catalogued as COSV100269752; called by muse, mutect2, varscan2
- COL6A3 | c.8147G>T p.G2716V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1311630536, COSV99796494, COSV99797536; called by muse, mutect2, varscan2
- CRB1 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100958448; called by muse, mutect2, varscan2
- CREBBP | c.798+1G>A p.X266_splice | Splice Site (SNP) | VAF 11/94 reads (12%) | catalogued as COSV99268866; called by muse, mutect2, varscan2
- CSMD3 | c.9362C>T p.A3121V (on ENST00000297405 / NM_001363185.1; = p.A2952V on NM_052900.3) | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.403); catalogued as rs1294622951, COSV52253092; called by muse, mutect2, varscan2
- CSMD3 | c.6816G>A p.W2272* (on ENST00000297405 / NM_001363185.1; = p.W2168* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99827313; called by muse, mutect2, varscan2
- CUL1 | c.1325T>G p.L442R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100296481; called by muse, mutect2, varscan2
- DEFB129 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.338); catalogued as COSV99857368; called by muse, mutect2, varscan2
- DLK2 | c.589T>C p.S197P | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99766832; called by muse, mutect2, varscan2
- DNAH7 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs565395707, COSV100414163; called by muse, mutect2, varscan2
- DUOX2 | c.3917C>T p.A1306V | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV101199604; called by muse, mutect2, varscan2
- EHD3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV100434637; called by muse, mutect2, varscan2
- ELAC1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.823); catalogued as rs779880681, COSV99494796; called by muse, mutect2, varscan2
- ERICH3 | c.3998G>A p.G1333E | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV58601275; called by muse, mutect2, varscan2
- FAM110B | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100826046; called by muse, mutect2, varscan2
- FAM135B | c.2470G>T p.G824* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV52717730, COSV99420182; called by muse, mutect2, varscan2
- FAM135B | c.675C>A p.S225R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99420190; called by muse, mutect2, varscan2
- FAM151B | c.79G>T p.A27S | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99971616; called by muse, mutect2, varscan2
- FAM153A | c.916A>T p.I306F | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.402); catalogued as COSV100646951; called by muse, mutect2, varscan2
- FBXO15 | c.1200C>G p.H400Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99503113; called by muse, mutect2, varscan2
- FILIP1L | c.2254C>G p.Q752E (on ENST00000354552 / NM_182909.3; = p.Q512E on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0.152); catalogued as COSV100496419; called by muse, mutect2, varscan2
- FMN2 | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100143466; called by muse, mutect2, varscan2
- FMO1 | c.1266G>T p.L422F | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs762510785; called by muse, mutect2
- FSTL1 | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 3/11 reads (27%) | catalogued as COSV55232082, COSV99820528; called by muse, mutect2
- FTMT | c.487G>T p.A163S | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100360248, COSV100360252; called by muse, mutect2, varscan2
- GH2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); catalogued as COSV100236853; called by muse, mutect2, varscan2
- GLI3 | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 21/211 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs144772281; ClinVar: uncertain significance; called by muse, mutect2
- GPA33 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 50/69 reads (72%) | catalogued as COSV100900947, COSV63300954; called by muse, mutect2, varscan2
- GPANK1 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV100788979; called by muse, mutect2, varscan2
- GPLD1 | c.890C>T p.S297L | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV100015098; called by muse, mutect2, varscan2
- GPR151 | c.762C>G p.S254R | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV99694493; called by muse, mutect2, varscan2
- GRIK3 | c.1937C>T p.T646M | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1277838021, COSV66135068; called by muse, mutect2, varscan2
- GRIN2A | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100408656, COSV58061724; called by muse, mutect2, varscan2
- GRK2 | c.1681A>G p.M561V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs1251480558, COSV100398345; called by muse, mutect2, varscan2
- HERC2 | c.7549G>A p.D2517N | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99871534; called by muse, varscan2
- HERC4 | c.1357A>T p.T453S | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99516677; called by muse, mutect2, varscan2
- HOXD3 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV99979945; called by mutect2, varscan2
- HTR3A | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100248305; called by muse, mutect2
- IL22RA2 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99760561; called by muse, mutect2, varscan2
- ITGAX | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.102); catalogued as rs369769686, COSV51645745; called by muse, mutect2, varscan2
- JAK2 | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV101070880; called by muse, mutect2, varscan2
- KBTBD13 | c.1186G>T p.A396S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV101416681; called by muse, mutect2, varscan2
- KIF4A | c.1432-2A>G p.X478_splice | Splice Site (SNP) | VAF 13/19 reads (68%) | catalogued as COSV100979422; called by muse, mutect2, varscan2
- KLF10 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs752020812, COSV99574632; called by muse, mutect2, varscan2
- KRT24 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 5/39 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.051); catalogued as COSV99231939; called by muse, mutect2
- LAMA5 | c.1936G>C p.A646P | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV99438472; called by muse, mutect2, varscan2
- LARP4B | c.305G>C p.G102A | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100295134; called by muse, mutect2, varscan2
- LRBA | c.8352C>T p.A2784= | Splice Region (SNP) | VAF 3/50 reads (6%) | catalogued as COSV100841035; called by muse, mutect2
- LRCH4 | c.275C>G p.S92C | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99575046; called by muse, mutect2, varscan2
- LRP1B | c.11600G>A p.C3867Y | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67275506; called by muse, mutect2, varscan2
- LRP1B | c.6300C>A p.D2100E | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV101253727; called by muse, mutect2, varscan2
- LRRK2 | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775681550, COSV100109445; called by muse, mutect2, varscan2
- LRRTM4 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as COSV101297436; called by muse, mutect2, varscan2
- MCF2L | c.979G>C p.A327P (on ENST00000375608; = p.A295P on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as COSV100982180; called by muse, mutect2, varscan2
- MCHR1 | c.794T>C p.I265T | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as rs1194035503, COSV99967754; called by muse, mutect2, varscan2
- MCM5 | c.356A>T p.E119V | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as COSV99331515; called by muse, mutect2, varscan2
- MFAP3 | c.803G>A p.G268D | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as COSV100491516; called by muse, mutect2, varscan2
- MNDA | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100933258; called by muse, mutect2, varscan2
- MON1B | c.1324G>T p.E442* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99941563, COSV99941843; called by muse, mutect2, varscan2
- MUC17 | c.4799C>A p.S1600Y | Missense Mutation (SNP) | VAF 36/499 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV60284345; called by muse, mutect2
- MYH11 | c.3351G>C p.E1117D | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.689); catalogued as COSV100257954; called by muse, mutect2, varscan2
- MYO16 | c.1882G>C p.D628H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as COSV99193619; called by muse, mutect2, varscan2
- NAV3 | c.5103+2T>C p.X1701_splice | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99887753; called by muse, mutect2, varscan2
- NDUFB5 | c.50C>G p.A17G | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99372470; called by muse, mutect2, varscan2
- NECTIN3 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100162172; called by muse, mutect2, varscan2
- NETO1 | c.512C>A p.A171E | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100198315, COSV100199928; called by muse, mutect2, varscan2
- NR1H4 | c.862-1G>T p.X288_splice (on ENST00000551379 / NM_001206993.2; = p.X274_splice on NM_005123.4) | Splice Site (SNP) | VAF 10/67 reads (15%) | catalogued as rs1053963172, COSV99500144, COSV99501356; called by muse, mutect2, varscan2
- NTRK3 | c.1945G>T p.G649C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs891767826, COSV100712342, COSV62300218; called by muse, mutect2, varscan2
- OBSCN | c.14685G>T p.Q4895H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99474302; called by muse, mutect2, varscan2
- OR4A5 | c.575T>C p.I192T | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.248); catalogued as rs1257764590, COSV100156986; called by muse, mutect2, varscan2
- OR4C15 | c.44G>A p.G15E | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100115438; called by muse, mutect2, varscan2
- OR4K13 | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100237656, COSV59859024; called by muse, mutect2, varscan2
- OR4N5 | c.77T>C p.L26P | Missense Mutation (SNP) | VAF 73/212 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV100374044; called by muse, mutect2, varscan2
- OR51I1 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV100970808; called by muse, mutect2, varscan2
- OR5D13 | c.549C>A p.H183Q | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV100686755; called by muse, mutect2, varscan2
- OR5T3 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100282703, COSV57382318; called by muse, mutect2, varscan2
- OR8H2 | c.938A>C p.*313Sext*3 | Nonstop Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as COSV100542175; called by muse, mutect2, varscan2
- OTULIN | c.360A>G p.I120M | Missense Mutation (SNP) | VAF 92/152 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); catalogued as rs753500942, COSV99419604; called by muse, mutect2, varscan2
- PASK | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs751298156, COSV99298832; called by muse, mutect2, varscan2
- PDE4D | c.2048G>T p.W683L (on ENST00000340635 / NM_001104631.2; = p.W547L on NM_006203.4) | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100401429; called by muse, mutect2, varscan2
- PHC1 | c.1249A>C p.T417P | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as COSV101418530; called by muse, varscan2
- PIWIL2 | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV100769259; called by muse, mutect2, varscan2
- PKHD1L1 | c.4921G>C p.G1641R | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101005554; called by muse, mutect2, varscan2
- PKM | c.1049A>G p.N350S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs1219959521, COSV100064573; called by muse, mutect2, varscan2
- PKN3 | c.2579C>T p.T860I | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99403354; called by muse, mutect2, varscan2
- PLCXD2 | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101210001; called by muse, mutect2, varscan2
- PLCXD2 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767184945, COSV101210003; called by muse, mutect2, varscan2
- PRB4 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 186/540 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.152); catalogued as rs766297108, COSV54398260, COSV99686366; called by muse, varscan2
- PSG8 | c.472C>A p.P158T | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV100126027, COSV60616067; called by muse, mutect2, varscan2
- PTK7 | c.2252G>C p.G751A | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.973); catalogued as COSV100029929; called by muse, mutect2, varscan2
- PZP | c.1011T>G p.S337R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.434); catalogued as COSV99736661; called by muse, mutect2
- RAB3IP | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV99922994; called by muse, mutect2, varscan2
- RDH8 | c.209C>A p.A70E (on ENST00000651512; = p.A50E on NM_015725.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99408556; called by muse, mutect2, varscan2
- RETREG2 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs955223684, COSV99811407; called by muse, mutect2, varscan2
- RPAP3 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99139285; called by mutect2, varscan2
- RXFP1 | c.479A>G p.N160S | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369527490, COSV100313586; called by muse, mutect2, varscan2
- RYR3 | c.3083G>T p.R1028L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.225); catalogued as COSV101212122, COSV66777575; called by muse, mutect2, varscan2
- SCN2A | c.2366G>A p.S789N | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51837604, COSV99330420; called by muse, mutect2, varscan2
- SCN8A | c.1052C>A p.T351K | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100633426; called by muse, mutect2
- SEMA3D | c.2053G>C p.E685Q | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.221); catalogued as COSV99406043; called by muse, mutect2, varscan2
- SEMA3E | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100317587; called by muse, mutect2
- SENP2 | c.1586G>T p.W529L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99957623; called by muse, mutect2, varscan2
- SH3TC2 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs138844518, COSV100101325; called by muse, varscan2
- SLC26A5 | c.939C>G p.Y313* | Nonsense Mutation (SNP) | VAF 9/113 reads (8%) | catalogued as COSV100098772; called by muse, mutect2
- SLC46A3 | c.189+1G>A p.X63_splice | Splice Site (SNP) | VAF 10/60 reads (17%) | catalogued as COSV99906149; called by muse, mutect2, varscan2
- SLC6A11 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as rs757433552, COSV54390218; called by muse, mutect2, varscan2
- SLC6A19 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as COSV100443287; called by muse, mutect2, varscan2
- SLIT3 | c.2542T>A p.S848T | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100265798, COSV60603506; called by muse, varscan2
- SNTG1 | c.875C>A p.A292D | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV99381905; called by muse, mutect2, varscan2
- SPATA6 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100893065; called by muse, mutect2, varscan2
- SRD5A2 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs752642171, COSV99252268; called by mutect2, varscan2
- ST3GAL5 | c.1031A>G p.N344S (on ENST00000377332; = p.N384S on NM_003896.4) | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV101061979; called by muse, mutect2, varscan2
- STRA8 | c.361G>C p.A121P (on ENST00000275764; = p.A99P on NM_182489.2) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV99312277; called by muse, mutect2, varscan2
- SYBU | c.496A>G p.T166A (on ENST00000276646 / NM_001099754.2; = p.T165A on NM_017786.6) | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99405801; called by muse, mutect2, varscan2
- TEX55 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.373); catalogued as COSV99817349; called by muse, mutect2, varscan2
- THOC5 | c.2014A>T p.K672* | Nonsense Mutation (SNP) | VAF 24/86 reads (28%) | catalogued as COSV100803477; called by muse, mutect2, varscan2
- THPO | c.422T>A p.M141K (on ENST00000649095 / NM_001290003.1; = p.M1? on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 258/510 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as COSV99200260; called by muse, mutect2, varscan2
- TMEM102 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.007); catalogued as rs372464277; called by muse, mutect2, varscan2
- TOM1 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101146577; called by muse, mutect2, varscan2
- TPSB2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52354914; called by muse, mutect2, varscan2
- TRRAP | c.3761C>A p.S1254Y | Missense Mutation (SNP) | VAF 58/86 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); catalogued as rs1295006765, COSV100722123; called by muse, mutect2, varscan2
- TSPAN8 | c.191C>G p.A64G | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV99922467; called by muse, mutect2, varscan2
- TTC13 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100792865; called by muse, mutect2, varscan2
- TTC3 | c.4189G>C p.G1397R | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs149029759; called by muse, mutect2, varscan2
- TTPA | c.757G>T p.E253* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV52645847, COSV99478420; called by muse, mutect2, varscan2
- TXNRD1 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs773611266, COSV101423557; called by muse, mutect2, varscan2
- UCP3 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs183714776, COSV100012903; called by muse, mutect2, varscan2
- VCAN | c.808T>A p.C270S | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424944; called by muse, mutect2, varscan2
- VGLL3 | c.905T>C p.V302A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.675); catalogued as COSV101051871; called by muse, mutect2, varscan2
- VPS8 | c.3540G>T p.M1180I (on ENST00000625842 / NM_001349294.1; = p.M1178I on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99800757; called by muse, mutect2, varscan2
- WDR62 | c.325A>T p.T109S | Missense Mutation (SNP) | VAF 157/279 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.434); catalogued as COSV99543277; called by muse, mutect2, varscan2
- ZBBX | c.2235G>T p.K745N | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV100283289; called by muse, mutect2, varscan2
- ZBTB20 | c.1121G>T p.S374I (on ENST00000474710 / NM_001164342.2; = p.S301I on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100612955; called by muse, mutect2, varscan2
- ZEB2 | c.990C>A p.S330R | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100355242; called by muse, mutect2, varscan2
- ZGPAT | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 30/93 reads (32%) | catalogued as COSV100157448; called by muse, mutect2, varscan2
- ZNF467 | c.1507G>A p.G503S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as COSV100117799; called by muse, mutect2, varscan2
- ZNF521 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV100831558; called by muse, mutect2, varscan2
- ZNF99 | c.232A>T p.S78C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.454); catalogued as COSV101233730; called by muse, mutect2, varscan2
- ZW10 | c.1058C>G p.T353R | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99562498; called by muse, mutect2
- DLG5 | c.3499C>T p.P1167S | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2
- EIF2AK4 | c.4716dup p.E1573* | Frame Shift Ins (INS) | VAF 16/75 reads (21%) | called by mutect2, pindel, varscan2
- HCN2 | c.1826-1_1840del p.X609_splice | Splice Site (DEL) | VAF 24/97 reads (25%) | called by mutect2, pindel
- IMPA2 | c.576del p.L193Cfs*11 | Frame Shift Del (DEL) | VAF 36/81 reads (44%) | called by mutect2, pindel, varscan2
- KRT13 | c.1181_1188del p.I394Tfs*34 (on ENST00000246635 / NM_153490.3; = p.I394Tfs*102 on NM_002274.4) | Frame Shift Del (DEL) | VAF 34/245 reads (14%) | called by mutect2, pindel, varscan2
- OR10AG1 | c.98_103del p.N33_G34del | In Frame Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2
- OR2T3 | c.900dup p.D301Rfs*? | Frame Shift Ins (INS) | VAF 48/261 reads (18%) | called by mutect2, varscan2
- STRAP | c.158G>C p.G53A | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WASHC2C | c.1423A>T p.K475* | Nonsense Mutation (SNP) | VAF 44/174 reads (25%) | called by muse, varscan2
- ZNF281 | c.1485_1486del p.L495Ffs*14 | Frame Shift Del (DEL) | VAF 46/100 reads (46%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.1992A>G p.A664= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1358545959, COSV101000097; called by muse, mutect2, varscan2
- AKAP6 | c.6282G>T p.V2094= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99798950; called by muse, mutect2, varscan2
- ARID5B | c.2529C>T p.H843= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99689179; called by muse, mutect2
- BRF1 | c.435G>T p.T145= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV100526915; called by muse, mutect2, varscan2
- C1QTNF7 | c.261G>T p.P87= | Silent (SNP) | VAF 34/85 reads (40%) | catalogued as rs144010767, COSV99765049; called by muse, mutect2, varscan2
- CDH10 | c.87G>T p.T29= | Silent (SNP) | VAF 82/150 reads (55%) | catalogued as COSV100050373, COSV52574516; called by muse, mutect2, varscan2
- CDK13 | c.1755A>G p.K585= | Silent (SNP) | VAF 52/78 reads (67%) | catalogued as COSV99475198; called by muse, mutect2, varscan2
- CENPJ | c.1500A>G p.K500= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV101121471; called by muse, mutect2, varscan2
- CHL1 | c.1335C>T p.C445= (on ENST00000397491 / NM_001253387.1; = p.C461= on NM_006614.4) | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs747335710, COSV56597177; called by muse, mutect2, varscan2
- CLTA | c.453C>T p.D151= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs758949311, COSV99643543; called by muse, mutect2, varscan2
- COL12A1 | c.7734G>T p.T2578= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100485531; called by muse, mutect2, varscan2
- COL8A1 | c.975C>A p.G325= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV99657270; called by muse, mutect2, varscan2
- CUL7 | c.756C>T p.S252= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV99538052; called by muse, mutect2, varscan2
- DCHS1 | c.5427C>T p.T1809= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100201608, COSV100202598; called by muse, mutect2, varscan2
- DMBT1 | c.6423A>G p.L2141= (on ENST00000338354 / NM_001377530.1; = p.L1384= on NM_004406.3) | Silent (SNP) | VAF 63/114 reads (55%) | catalogued as rs369857130; called by muse, mutect2, varscan2
- DOCK7 | c.870C>T p.V290= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1405369707, COSV99223272; called by muse, mutect2, varscan2
- EAPP | c.198A>G p.E66= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV99164218; called by muse, mutect2, varscan2
- EXOC4 | c.1686C>T p.A562= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99552664; called by muse, mutect2, varscan2
- FAM135B | c.2469T>C p.A823= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV52737479; called by muse, mutect2, varscan2
- FLNA | c.5934G>T p.T1978= (on ENST00000369850 / NM_001110556.2; = p.T1970= on NM_001456.3) | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as COSV100774238, COSV100774347; called by muse, mutect2, varscan2
- ICE1 | c.4713A>T p.S1571= | Silent (SNP) | VAF 28/49 reads (57%) | catalogued as COSV99663987; called by muse, mutect2, varscan2
- KCNH8 | c.471G>A p.G157= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100108821; called by muse, mutect2, varscan2
- KCNJ13 | c.96T>C p.D32= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99289247; called by muse, mutect2, varscan2
- KCNK9 | c.792C>T p.L264= | Silent (SNP) | VAF 31/99 reads (31%) | catalogued as rs574258393, COSV57281882; called by muse, mutect2, varscan2
- KCNT1 | c.63C>A p.G21= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV100039884; called by muse, mutect2, varscan2
- LMOD2 | c.73C>T p.L25= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV101505416; called by muse, mutect2
- LRRN2 | c.765G>A p.R255= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as COSV100912772; called by muse, mutect2, varscan2
- MAST1 | c.2271C>A p.G757= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs764541898, COSV52250762, COSV99262462; called by muse, mutect2
- MEN1 | c.1407G>A p.A469= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as rs754445482, CD035819, COSV99580505; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC16 | c.39909G>T p.P13303= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101109674; called by muse, mutect2, varscan2
- MUC17 | c.4800C>A p.S1600= | Silent (SNP) | VAF 36/499 reads (7%) | catalogued as COSV100072003; called by muse, mutect2
- MYL10 | c.345G>T p.A115= | Silent (SNP) | VAF 41/67 reads (61%) | catalogued as rs375406824, COSV56207128; called by muse, mutect2, varscan2
- NAALAD2 | c.570T>C p.I190= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV100428129; called by muse, mutect2, varscan2
- NKX2-2 | c.504G>T p.T168= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV101010477, COSV101010516; called by muse, mutect2, varscan2
- NOTUM | c.537C>T p.F179= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs530981918, COSV101293759; called by muse, mutect2, varscan2
- NOX5 | c.1218C>G p.L406= | Silent (SNP) | VAF 55/216 reads (25%) | catalogued as COSV99533408; called by muse, mutect2, varscan2
- OR4C12 | c.252T>C p.F84= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV100078326; called by muse, mutect2, varscan2
- PLSCR1 | c.714C>T p.S238= | Silent (SNP) | VAF 32/166 reads (19%) | catalogued as rs1261766719, COSV100678321; called by muse, mutect2, varscan2
- PTPN13 | c.5976G>T p.V1992= (on ENST00000411767 / NM_080683.3; = p.V1973= on NM_006264.3) | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV57420714; called by muse, mutect2, varscan2
- RADIL | c.3225C>G p.L1075= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV68200935; called by muse, mutect2, varscan2
- SNTG1 | c.876C>G p.A292= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV99381907; called by muse, mutect2, varscan2
- SPATA2L | c.1071A>G p.A357= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99232123; called by muse, mutect2, varscan2
- SYTL2 | c.663G>A p.L221= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100313762; called by muse, mutect2, varscan2
- TBXAS1 | c.477C>T p.C159= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as rs371594766; called by muse, mutect2, varscan2
- TBXT | c.816C>A p.S272= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as COSV99752154; called by muse, mutect2, varscan2
- TEP1 | c.1947T>C p.G649= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV99401806; called by muse, mutect2
- THAP12 | c.613C>T p.L205= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99472787; called by muse, mutect2, varscan2
- THSD7B | c.3831C>A p.I1277= (on ENST00000272643; = p.I1275= on NM_001316349.2) | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as COSV99745776, COSV99759539; called by muse, mutect2, varscan2
- TNN | c.2997G>A p.Q999= | Silent (SNP) | VAF 21/154 reads (14%) | catalogued as COSV99511284; called by muse, mutect2, varscan2
- TTN | c.16017G>A p.L5339= (on ENST00000591111; = p.L4412= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV100598504; called by muse, mutect2, varscan2
- ZNF423 | c.1932A>G p.Q644= (on ENST00000563137 / NM_001379286.1; = p.Q636= on NM_015069.4) | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs765545274, COSV99280312; called by muse, mutect2, varscan2
- ZNF518B | c.2193T>C p.G731= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV100456588; called by muse, mutect2, varscan2
- ZNF626 | c.711C>A p.A237= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV101656952; called by muse, mutect2, varscan2
- CNTN1 | c.1805-9436C>T | Intron (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100751039; called by muse, mutect2, varscan2
- DCHS2 | n.383G>T | RNA (SNP) | VAF 23/60 reads (38%) | catalogued as rs548734507, COSV100251095; called by muse, mutect2, varscan2
- MIR1246 | n.21dup | RNA (INS) | VAF 15/154 reads (10%) | called by mutect2, pindel, varscan2
- MIR409 | n.66C>T | RNA (SNP) | VAF 20/82 reads (24%) | called by mutect2, varscan2
- SDHD | c.-1G>C | 5'UTR (SNP) | VAF 15/79 reads (19%) | catalogued as COSV99735938; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1533G>A | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100313760; called by muse, mutect2, varscan2
- ZNF783 | c.802+3014A>T | Intron (SNP) | VAF 19/150 reads (13%) | catalogued as COSV100954168; called by muse, mutect2, varscan2
